Surgical pathology report (de-identified scan), TCGA case TCGA-29-2425, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-2425-01A (Primary Tumor).

[page 1 of 3]
TCGA-29-2425

Surg Path

CLINICAL HISTORY:

Abdominal/pelvic swelling, large pelvic mass with history of breast cancer.

GROSS EXAMINATION:

A. "Omental nodule (AF1)". Received fresh is a 7.8 x 4.9 x 2.1 cm fragment of yellow-tan lobulated fibroadipose tissue that contains a 2.2 x 2.1 x 1.4 cm well circumscribed, tan-white, firm nodule (AF1 Frozen section; remnant in A1; additional A2).

B. "Piece of omentum". Received fresh is a 16.9 x 10.6 x 3.2 cm aggregate of two fragments of yellow-tan lobulated fibrofatty tissue that discloses no masses (B1-2).

C. "Right tube and ovary". Received fresh is a 650 gram, 15.0 x 11.0 x 9.0 cm ovarian tumor with an attached 10.2 x 0.7 cm expanded pink-tan fallopian tube. The external surface of the ovarian tumor is tan-white, focally erythematous, intact without excrescences or evidence of rupture. The specimen is serially sectioned to exhibit a predominantly solid cut surface which is variegated tan-yellow to gray-tan and which varies in consistency from very firm to friable and fleshy. Interspersed throughout the cut surface are multiple smooth walled cysts, maximally 4.6 cm, filled with clear tan fluid. The cut surface also exhibits inter twining bands of white-tan fibrous tissue and focal areas of degeneration and necrosis. The fallopian tube exhibits a 0.1 cm in diameter patent lumen and two 6 mm paratubal cysts

BLOCK SUMMARY:

- C1- fallopian tube with adjacent ovarian mass
- C2- fibromembranous adhesion with adjacent ovarian mass
- C3-5- ovarian mass with capsule
- C6-8- representative ovarian mass

D. "Left tube and ovary". Received fresh is a 300 gram, 9.9 x 8.4 x 6.6 cm ovary with an attached 3.2 x 2.2 x 0.9 cm portion of adhered, fimbriated fallopian tube. Adjacent is a 7.3 x 5.7 cm area of tan-yellow to tan-pink fibrofatty adhesion which is inked blue. The external ovary is smooth, glistening, tan-white to tan-pink and is intact. The ovary is serially sectioned to exhibit the predominantly solid variegated tan-yellow to gray-pink cut surface with inter twinning bands of firm tan-white fibrous tissue and multiple smooth walled cyst up to 1.1 cm in greatest dimension filled with clear tan fluid. The cut surface varies in consistency from very firm to somewhat friable. The portion of fimbriated fallopian tube present is adhered upon itself, and upon sectioning, a 0.2 cm in diameter lumen is identified.

BLOCK SUMMARY:

- D1- tube with adjacent ovary, and additional tube
- D2- ovary with blue-inked adhesion
- D3- ovary with capsule
- D4- ovary

E. "Uterus". Received fresh is a 97.1 gram, 8.5 x 5.2 x 2.0 cm uterus. The serosa is pink-tan, glistening and exhibits multiple red-brown hemorrhagic adhesions both anteriorly and posteriorly. The 2.7 cm cervix exhibits a pink-tan, focally erythematous ectocervix with a 0.2 cm os which opens into a yellow-tan trabeculated endocervical canal. The opened specimen reveals a 3.8 x 2.2 cm endometrial cavity with two broad based endometrial polyps up to 1.9 x 1.7 x 0.6 cm in the posterior cavity. The smaller polyp is in the fundus, while the larger polyp is near the posterior lower uterine segment. The

[page 2 of 3]
uninvolved endometrium is tan-brown and 0.1 cm thick. The 1.7 cm thick pink-tan myometrium exhibits a single white-tan, whorled, well-circumscribed intramural leiomyoma up to 0.6 cm in greatest dimension in the anterior half of the specimen.

BLOCK SUMMARY:

- E1- anterior cervix
- E2- posterior cervix
- E3- anterior endomyometrium with leiomyoma
- E4-5- posterior endomyometrium with fundic endometrial polyp, bisected
- E6- additional endometrial polyp in serosal adhesions

F. "Cul de sac tumor", received fresh and placed in formalin. A 5.1 x 3.5 x 3.1 cm nodular fragment of tan-white to pink-tan tissue which is somewhat encapsulated. However there is a 2.3 x 1.1 cm focal disruption which exposes the underlying tan-white, friable tumor. Upon sectioning, the cut surface is pink-tan; glistening and soft. Representative in F1-2.

G. "Left aortic node", received fresh and placed in formalin. A 3.1 x 0.9 x 0.9 cm fragment of gray-tan tissue is sectioned and is entirely submitted in G1.

INTRA OPERATIVE CONSULTATION:

- A. "Omental nodule": carcinoma present

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

HYSTERECTOMY, OOPHORECTOMY & LYMPH NODES:

C. "RIGHT OVARY":

TYPE: SEROUS ADENOCARCINOMA
FIGO GRADE: 2 (BUT WITH SUBSTANTIAL AREAS OF GRADE 3 IN THE OVARY AND EXTENSIVE GRADE 3 IN METASTASES).
TUMOR SIZE: 15.0 X 11.0 X 9.0 CM.
WEIGHT: 650 GRAMS
SEROA: INVOLVED
ADDITIONAL FINDINGS: NONE
PATH STAGING: 3C FIGO.

SPECIMENS WITH METASTATIC/IMPLANTED TUMOR:

- A. OMENTAL NODULE.
- D. LEFT OVARY (THIS MAY BE PRIMARY ALSO)
- F. CUL DE SAC TUMOR:

SPECIMEN FREE OF TUMOR:

- B. PIECE OF OMENTUM: NO TUMOR IN 3 LYMPH NODES (0/3).
- D. LEFT FALLOPIAN TUBE.
- E. UTERUS, 97.0 GRAMS
- ENDOMETRIUM: QUIESCENT
- POLYPS
- MYOMETRIUM: LEIOMYOMA
- CERVIX & SEROSA: NO PATHOLOGIC DIAGNOSIS
- G. LEFT AORTIC LYMPH NODE: FIBROFATTY TISSUE.

NOTE: Information on pathology staging and the operative procedure is being transmitted to this Institution's Cancer Registry as required for accreditation purposes by the Commission on Cancer. Pathology staging is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Anatomic pathology staging is only a component to be considered in determining the clinical stage, but should not be confused with nor substituted for it. The exact operative procedure is available in the

[page 3 of 3]
surgeon's operative report.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 5ad09933-4ad1-4d8b-9d3c-257508e10fe1 (TCGA-29-2425.EC04E6AE-AE66-4FC2-B77B-485F77CE39BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).